Somatic mutation profile of tumor specimen ALCH-B1QL-TTP1-B (aliquot ALCH-B1QL-TTP1-B-1-0-D-A81V-36) from ALCHEMIST case ALCH-B1QL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 60.9 years (22,258 days).
Specimen ALCH-B1QL-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 579dd6cb-5ecf-4621-b239-6cac912390be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1QL-NB1-A (Blood Derived Normal), aliquot ALCH-B1QL-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/512628a9-94a4-401c-b7de-55ca303b8044

The open-access MAF lists 2 somatic variants for this specimen: 2 silent.
By variant classification: Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MED26 | c.1078C>T p.L360= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV54663788; called by muse, mutect2
- PKD1 | c.12831C>T p.A4277= (on ENST00000262304 / NM_001009944.3; = p.A4276= on NM_000296.4) | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs764528545; called by muse, mutect2
